MMRF case MMRF_2297 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/e84e1504-6f13-4ac8-a4ce-6af61b2c8786

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Age at index: 58 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 58.2 years (21,262 days); ISS stage: II; Days to last known disease status: 793 days (2.2 years); Days to last follow up: 793 days (2.2 years).
   Treatment given: Therapeutic agents: Bortezomib; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 24 days.
   Treatment given: Therapeutic agents: Dexamethasone + Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 48 days.
   Treatment given: Therapeutic agents: Bortezomib + Dexamethasone + Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 76 days; Days to treatment end: 198 days.
   Treatment given: Therapeutic agents: Melphalan; Regimen or line of therapy: First line of therapy; Days to treatment start: 274 days; Days to treatment end: 275 days.
   Treatment given: Treatment type: Stem Cell Transplantation, Autologous; Regimen or line of therapy: First line of therapy; Days to treatment start: 276 days; Days to treatment end: 276 days.
   Treatment given: Therapeutic agents: Bortezomib; Regimen or line of therapy: First line of therapy; Days to treatment start: 406 days (1.1 years).

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day 1 (ECOG 0): M Protein 4.6 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.29 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.42 mg/dL; Immunoglobulin G 52.9 g/L; Immunoglobulin A 0.63 g/L; Immunoglobulin M 0.3 g/L; Beta 2 Microglobulin 1.8 µg/mL; Lactate Dehydrogenase 2.18 µkat/L; Hemoglobin 7.63 mmol/L; Leukocytes 4.39 ×10⁹/L; Absolute Neutrophil 2.31 ×10⁹/L; Platelets 166 ×10⁹/L; Creatinine 69 µmol/L; Blood Urea Nitrogen 5 mmol/L; Calcium 2.13 mmol/L; Albumin 28 g/L; Total Protein 9.8 g/dL; Glucose 4.68 mmol/L; C-Reactive Protein 0.29 mg/dL.
- Day 84 (ECOG 1): M Protein 0.9 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 3.22 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.74 mg/dL; Immunoglobulin G 17 g/L; Immunoglobulin A 4.75 g/L; Immunoglobulin M 0.48 g/L; Hemoglobin 7.5 mmol/L; Leukocytes 4.3 ×10⁹/L; Absolute Neutrophil 2.2 ×10⁹/L; Platelets 202 ×10⁹/L; Creatinine 53 µmol/L; Blood Urea Nitrogen 5 mmol/L; Calcium 2.38 mmol/L; Albumin 32 g/L; Total Protein 8.2 g/dL; Glucose 7.04 mmol/L.
- Day 168 (ECOG 0): M Protein 0.5 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.92 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.81 mg/dL; Immunoglobulin G 9.12 g/L; Immunoglobulin A 1.16 g/L; Immunoglobulin M 0.35 g/L; Lactate Dehydrogenase 2.6 µkat/L; Hemoglobin 8.87 mmol/L; Leukocytes 4.2 ×10⁹/L; Absolute Neutrophil 2.9 ×10⁹/L; Platelets 184 ×10⁹/L; Creatinine 79.6 µmol/L; Blood Urea Nitrogen 5.71 mmol/L; Calcium 2.28 mmol/L; Albumin 38 g/L; Total Protein 6.8 g/dL; Glucose 5.12 mmol/L.
- Day 269 (ECOG 0): M Protein 0.3 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.63 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.13 mg/dL; Immunoglobulin G 7.18 g/L; Immunoglobulin A 1.54 g/L; Immunoglobulin M 0.36 g/L; Lactate Dehydrogenase 5.75 µkat/L; Hemoglobin 8.56 mmol/L; Leukocytes 48.5 ×10⁹/L; Absolute Neutrophil 38.2 ×10⁹/L; Platelets 146 ×10⁹/L; Creatinine 65.4 µmol/L; Blood Urea Nitrogen 3.93 mmol/L; Calcium 2.15 mmol/L; Albumin 35 g/L; Total Protein 6.6 g/dL; Glucose 6.88 mmol/L.
- Day 352 (ECOG 1): Serum Free Immunoglobulin Light Chain, Kappa 1.31 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.19 mg/dL; Immunoglobulin G 8.44 g/L; Immunoglobulin A 1.82 g/L; Immunoglobulin M 0.29 g/L; Hemoglobin 7.81 mmol/L; Leukocytes 5.3 ×10⁹/L; Absolute Neutrophil 3.4 ×10⁹/L; Platelets 142 ×10⁹/L; Creatinine 61.9 µmol/L; Blood Urea Nitrogen 3.93 mmol/L; Calcium 2.38 mmol/L; Albumin 38 g/L; Total Protein 7 g/dL; Glucose 5.28 mmol/L.
- Day 441 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.4 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.08 mg/dL; Immunoglobulin G 7.34 g/L; Immunoglobulin A 1.6 g/L; Immunoglobulin M 0.44 g/L; Hemoglobin 8.06 mmol/L; Leukocytes 4 ×10⁹/L; Absolute Neutrophil 2.6 ×10⁹/L; Platelets 110 ×10⁹/L; Creatinine 61.9 µmol/L; Blood Urea Nitrogen 5.36 mmol/L; Calcium 2.23 mmol/L; Albumin 38 g/L; Total Protein 6.8 g/dL; Glucose 7.1 mmol/L.
- Day 540 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.12 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.47 mg/dL; Immunoglobulin G 7.67 g/L; Immunoglobulin A 1.89 g/L; Immunoglobulin M 0.5 g/L; Hemoglobin 8.8 mmol/L; Leukocytes 5.8 ×10⁹/L; Absolute Neutrophil 3.8 ×10⁹/L; Platelets 123 ×10⁹/L; Creatinine 61.9 µmol/L; Blood Urea Nitrogen 5.71 mmol/L; Calcium 2.35 mmol/L; Albumin 41 g/L; Total Protein 7 g/dL; Glucose 8.09 mmol/L.
- Day 616: M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 3.75 mg/dL; Immunoglobulin G 8 g/L; Immunoglobulin A 2.43 g/L; Immunoglobulin M 1.83 g/L; Hemoglobin 8.31 mmol/L; Leukocytes 4.9 ×10⁹/L; Absolute Neutrophil 2.7 ×10⁹/L; Platelets 119 ×10⁹/L; Creatinine 79.6 µmol/L; Blood Urea Nitrogen 5.36 mmol/L; Calcium 2.38 mmol/L; Albumin 36 g/L; Total Protein 7 g/dL; Glucose 5.28 mmol/L.
- Day 728: M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.52 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.32 mg/dL; Immunoglobulin G 7.11 g/L; Immunoglobulin A 1.98 g/L; Immunoglobulin M 0.56 g/L; Hemoglobin 8.8 mmol/L; Leukocytes 5.9 ×10⁹/L; Absolute Neutrophil 3 ×10⁹/L; Platelets 127 ×10⁹/L; Creatinine 61.9 µmol/L; Blood Urea Nitrogen 4.28 mmol/L; Calcium 2.25 mmol/L; Albumin 38 g/L; Total Protein 7 g/dL; Glucose 6.38 mmol/L.
- Day 793: M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.47 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.27 mg/dL; Immunoglobulin A 2.07 g/L; Immunoglobulin M 0.51 g/L; Hemoglobin 9.11 mmol/L; Leukocytes 6.9 ×10⁹/L; Absolute Neutrophil 3.4 ×10⁹/L; Platelets 127 ×10⁹/L; Creatinine 61.9 µmol/L; Blood Urea Nitrogen 5 mmol/L; Calcium 2.3 mmol/L; Albumin 37 g/L; Total Protein 6.7 g/dL; Glucose 5.23 mmol/L.

Other clinical attributes
- Day 1: Weight: 80 kg; Height: 177 cm.

Family history
- Relative with cancer history: no.

Biospecimens (2 samples)
- Sample MMRF_2297_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: 1 day.
- Sample MMRF_2297_1_PB_Whole: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: 1 day.
